Surgical pathology report (de-identified scan), TCGA case TCGA-XD-AAUG, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Providence Portland Medical Center, specimen TCGA-XD-AAUG-01A (Primary Tumor).

[page 1 of 4]
Collected date and time:

Clinical Information

Unspecified disease of pancreas

Surg Path Addendum

This addendum is to correct the tumor location from pancreatic neck to distal pancreas in Pathology Synoptic Report as follows:

Tumor location: distal pancreas by history

Per conversation with the metastatic pancreatic carcinoma infiltrates the posterior cervix rather than the anterior cervix. Therefore, the diagnosis of specimen C is amended as follows:

C. UTERUS, TUBES, OVARIES, HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

- Metastatic pancreatic adenocarcinoma diffusely infiltrating posterior cervical wall
- Atrophic endometrium with a benign endometrial polyp
- Uterine leiomyoma with hyalinizing degeneration
- Benign serous cyst of right ovary
- Paratubal cyst of left fallopian tube
- Left ovary and right fallopian tube, no specific pathologic changes

There are no changes to the remainder of the diagnosis and pathology synoptic.

Original report verified

-----end of addendum-----

Diagnosis

A. PANCREAS, NEAR TOTAL PANCREATECTOMY:

- Ductal adenocarcinoma of pancreas, moderately to poorly differentiated, approximate tumor size 3.2 x 2.4 cm
- Tumor focally extending to peripancreatic fat
- Extensive perineural invasion by carcinoma identified
- Focally suspicious for lymphatic space invasion
- Stabled pancreatic margin containing pancreatic duct, negative for invasive carcinoma (see comment)

ICD-6-B

Adenocarcinoma, duct NOS 8500.3

Site ^{CX} Pancreas body C25.1

^{path} Pancreas neck C25.7

W 5/21/14

[page 2 of 4]
- Carcinoma focally extending to less than 1 mm of inked peripancreatic soft tissue margin
- Metastatic adenocarcinoma involving one out of twelve peripancreatic lymph nodes (1/12)
- Marked dilatation of pancreatic duct with focal Pancreatic Intraepithelial Neoplasia 2 (PanIN-2)

B. SPLEEN, SPLENECTOMY:

- Congestion of splenic red pulp, negative for tumor

C. UTERUS, TUBES, OVARIES, HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:

- Metastatic pancreatic adenocarcinoma involving anterior cervical wall
- Atrophic endometrium with a benign endometrial polyp
- Uterine leiomyoma with hyalinizing degeneration
- Benign serous cyst of right ovary
- Paratubal cyst of left fallopian tube
- Left ovary and right fallopian tube, no specific pathologic changes

Comment: The stapled pancreatic parenchymal margin containing pancreatic duct is free of invasive carcinoma; there is Pancreatic Intraepithelial Neoplasia 1B (PanIN-1B) involving the pancreatic ductal margin.

This case was reviewed at the

Pathology Synoptic

Specimen type: Near total pancreatectomy, splenectomy, hysterectomy and bilateral salpingo-oophorectomy

Tumor location: Pancreatic neck per history

Histologic type: Ductal adenocarcinoma

Histologic grade: Moderately to poorly differentiated

Tumor size: 3.2 x 2.4 cm

Invasion of:

Tumor extends beyond the pancreas, but without involvement of celiac axis or SMA

Lymphatic invasion: Suspicious

Large vessel invasion: Not identified

Margins:

Common bile duct: NA

Proximal duodenal or gastric margin: N/A

Distal duodenal margin: N/A

Proximal pancreatic margin: Negative for invasive carcinoma; the pancreatic duct margin shows

PanIN-1B

Peripancreatic soft tissue margin: Negative; carcinoma focally extends to less than 1 mm of peripancreatic soft tissue margin (cytokeratin stain highlights cancer glands)

Total regional lymph nodes: 12 Number positive: 1

AJCC Pathologic Stage: pT3, N1, M1

Dictated and authenticated by:

[page 3 of 4]
Performing Location:

Gross Description

A. PANCREAS

Received fresh labeled with the patient name

Description: Unoriented 46 g, 9.2 x 3.5 x 2.8 cm segment of pancreas with the tenuously attached 12 x 10 x 1.5 cm portion of omental apron. Duodenum and bile ducts are not present. Prior to sectioning the stapled margin of the pancreas is stained with green dye. As the pancreas is received without orientation, all remaining surfaces are stained black. A poorly defined 3.2 x 2.4 x 1.7 cm tumor is found approximately 2 cm from the stapled margin. The tumor is grossly free of all margins. Much of the pancreas demonstrates dilated pancreatic ducts, fat necrosis and fibrosis. There is no gross appearance of tumor involving the omentum. The specimen is dissected for lymph nodes.

SECTIONS:

- A1. Stapled margin en face
- A2-5. All of the tumor
- A6-11 sequential sections of the adjacent fibrosed pancreas
- A12-14. 9 representative sections of the omentum
- A15. 4 lymph nodes
- A16. One lymph node trisected and all submitted

B. SPLEEN:

Received in formalin labeled with the patient name

Description: 98 g, 6.2 x 5.2 x 4.9 cm partially disrupted spleen. Hilar fat reveals no gross lymph nodes or accessory spleen. The cut surfaces are homogeneous, white pulp is well delineated, no gross appearance of tumor.

SECTIONS:

- B1-2. Representative sections

C. UTERUS, TUBES, OVARIES

Received in formalin labeled with the patient name

Specimen received: Uterus with attached right fallopian tube and ovary, left fallopian tube and separately submitted left ovary

Integrity: Received disrupted

Weight and size of uterus with cervix: 45 g, 6.8 x 5.7 x 4.9 cm

Serosa: Posterior serosa is roughened

Endometrial cavity: 4.3 x 1.4 cm, endometrium averages 0.1 cm in thickness, 1.5 x 1.0 x 0.4 cm posterior fundic endometrial polyp

Myometrium: Myometrial wall averages 1 cm in thickness, 0.6 cm anterior intramural myoma

Cervix: 1.8 cm in diameter, exocervix congested and roughened

Right ovary: 1.1 x 1.0 x 0.8 cm containing a 0.9 cm serous cyst

[page 4 of 4]
Right fallopian tube: 4.2 x 0.6 cm, no gross abnormality
Left ovary: 1.1 x 1.1 x 0.6 cm, roughened serosa
Left fallopian tube: 4.3 x 0.6 cm, no gross abnormality

SECTIONS:

- C1. Posterior cervix
- C2. AnteriorPosterior cervix
- C3. 2 full-thickness sections of the anterior uterine wall with all of the myoma
- C4-5. 2 full-thickness sections of the posterior uterine wall to include all of the endometrial polyp
- C6. All of the right ovary
- C7. 2 cross sections of right fallopian tube and all of the right fimbriated end in longitudinal section
- C8. All of the left ovary in 2 sections
- C9. 2 cross sections of left fallopian tube and all of the fimbriated end in longitudinal section

Surg Path Non-Chartable Comment

Edited by:

Source: NCI Genomic Data Commons file 6b36fd5b-c54b-4415-87df-8fb2db6dbccd (TCGA-XD-AAUG.5980FD31-6C96-45D0-8324-5D777942D391.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).